Somatic mutation profile of tumor specimen C3N-00179-03 (aliquot CPT0019940009_1) from CPTAC case C3N-00179, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 69.5 years (25,370 days).
Specimen C3N-00179-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 461d396a-3a49-4770-8e28-3c5a35d2d080.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00179-31 (Blood Derived Normal), aliquot CPT0020950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/52a92d3c-c78c-4ede-bc72-aa9745d00b05

The open-access MAF lists 48 somatic variants for this specimen: 28 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 13, Intron 4, 3'UTR 2, Nonsense Mutation 2, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.6977G>T p.R2326L | Missense Mutation (SNP) | VAF 48/225 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137852360, CD101348, CM012947, CM860009, CM890047, COSV100371798; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 107/272 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGEF28 | c.2063T>C p.V688A | Missense Mutation (SNP) | VAF 24/307 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as rs1258471558; called by muse, mutect2
- AVIL | c.2449G>A p.G817R | Missense Mutation (SNP) | VAF 52/502 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs201808188; called by muse, varscan2
- BTNL3 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 24/383 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61564956; called by muse, mutect2
- DNAJC13 | c.4480A>T p.I1494F | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99608162; called by muse, mutect2, varscan2
- GOLGA6L7 | c.1309G>T p.G437W | Missense Mutation (SNP) | VAF 80/609 reads (13%) | SIFT tolerated (0.19); catalogued as rs1241403287; called by muse, mutect2
- KRTAP5-3 | c.581G>C p.C194S | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs527598636, COSV68790660; called by muse, varscan2
- OR2B3 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 68/525 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs761688447, COSV65851237; called by muse, mutect2, varscan2
- PSMD3 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52860041; called by muse, mutect2
- SLC1A4 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 37/300 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768616901, COSV52235413; called by muse, mutect2, varscan2
- TNRC6B | c.3790C>T p.Q1264* (on ENST00000454349 / NM_001162501.2; = p.Q1154* on NM_015088.3) | Nonsense Mutation (SNP) | VAF 24/454 reads (5%) | catalogued as COSV57306177; called by muse, mutect2
- TTPA | c.314G>C p.R105T | Missense Mutation (SNP) | VAF 34/576 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.131); catalogued as COSV52647734; called by muse, mutect2
- ZNF451 | c.2897A>G p.D966G (on ENST00000370706 / NM_001031623.3; = p.D918G on NM_015555.2) | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758659256; called by mutect2, varscan2
- ACSBG2 | c.1235T>C p.L412S | Missense Mutation (SNP) | VAF 28/390 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATP1A2 | c.750C>T p.G250= | Splice Region (SNP) | VAF 37/249 reads (15%) | called by muse, mutect2, varscan2
- CHGB | c.541G>C p.D181H | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); called by muse, mutect2
- CPNE2 | c.992A>G p.N331S | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0.023); called by muse, mutect2
- DOCK2 | c.137G>T p.R46M | Missense Mutation (SNP) | VAF 29/321 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2
- KMO | c.1128C>A p.F376L | Missense Mutation (SNP) | VAF 31/297 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- KMT5B | c.2596T>A p.S866T | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LMAN1L | c.1465A>G p.K489E | Missense Mutation (SNP) | VAF 36/255 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LTB4R | c.433T>G p.S145A | Missense Mutation (SNP) | VAF 78/371 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MSN | c.572A>G p.Y191C | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR13C4 | c.853G>T p.G285W | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.697); called by muse, mutect2
- OS9 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 89/795 reads (11%) | called by muse, mutect2, varscan2
- SCNN1A | c.1969G>T p.A657S | Missense Mutation (SNP) | VAF 54/421 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF808 | c.1244C>A p.A415E | Missense Mutation (SNP) | VAF 26/365 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.026); called by muse, mutect2
- ACTR8 | c.432A>T p.R144= | Silent (SNP) | VAF 18/268 reads (7%) | catalogued as COSV99213707; called by muse, mutect2
- CARD14 | c.642G>T p.L214= | Silent (SNP) | VAF 68/321 reads (21%) | called by muse, mutect2, varscan2
- CEACAM1 | c.483T>C p.D161= | Silent (SNP) | VAF 44/448 reads (10%) | called by muse, mutect2
- DOK4 | c.198G>A p.K66= | Silent (SNP) | VAF 28/197 reads (14%) | catalogued as COSV99538257; called by muse, mutect2, varscan2
- DPY19L2 | c.1962C>A p.P654= | Silent (SNP) | VAF 32/334 reads (10%) | called by muse, mutect2
- IKBKE | c.684G>A p.R228= | Silent (SNP) | VAF 16/398 reads (4%) | catalogued as rs1231278650; called by muse, mutect2
- KRTAP5-3 | c.570C>T p.C190= | Silent (SNP) | VAF 58/192 reads (30%) | catalogued as rs12808755, COSV68791240; called by muse, varscan2
- MOGAT2 | c.514C>T p.L172= | Silent (SNP) | VAF 95/456 reads (21%) | catalogued as rs1033718862, COSV99549592; called by muse, mutect2, varscan2
- MTBP | c.216T>A p.G72= | Silent (SNP) | VAF 19/412 reads (5%) | called by muse, mutect2
- NPIPB2 | c.1095A>G p.E365= (on ENST00000399147; = p.E225= on NM_001355514.1) | Silent (SNP) | VAF 40/300 reads (13%) | catalogued as rs79845530, COSV63638523; called by muse, varscan2
- RPUSD2 | c.1566C>T p.R522= | Silent (SNP) | VAF 44/256 reads (17%) | called by muse, mutect2, varscan2
- SVIL | c.561C>T p.L187= | Silent (SNP) | VAF 32/356 reads (9%) | catalogued as COSV63447209; called by muse, mutect2
- ZHX1 | c.1488A>G p.R496= | Silent (SNP) | VAF 30/442 reads (7%) | called by muse, mutect2
- ACSS3 | c.*2G>A | 3'UTR (SNP) | VAF 20/257 reads (8%) | catalogued as rs192386241, COSV99698160; called by muse, mutect2
- CFAP92 | c.*129G>A | 3'UTR (SNP) | VAF 18/265 reads (7%) | called by muse, mutect2
- ITGB3BP | c.6-1602C>T | Intron (SNP) | VAF 16/200 reads (8%) | catalogued as rs960046344, COSV52132683; called by muse, mutect2
- KIF7 | c.2593-24C>T | Intron (SNP) | VAF 32/126 reads (25%) | catalogued as rs760175118; called by muse, mutect2, varscan2
- MLIP | c.612+11989G>A | Intron (SNP) | VAF 54/307 reads (18%) | called by muse, mutect2, varscan2
- PRB3 | c.605-44C>T | Intron (SNP) | VAF 56/112 reads (50%) | catalogued as rs1157195492; called by muse, varscan2
- TMEM167A | c.-47C>T | 5'UTR (SNP) | VAF 40/212 reads (19%) | called by muse, mutect2, varscan2
